Somatic mutation profile of tumor specimen TARGET-10-PANWJM-09A (aliquot TARGET-10-PANWJM-09A-01D) from TARGET case TARGET-10-PANWJM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,896 days).
Specimen TARGET-10-PANWJM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc69d6dc-4d84-4b77-af97-03f42bd7ef0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANWJM-10A (Blood Derived Normal), aliquot TARGET-10-PANWJM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5843f26f-3192-487e-a59b-ea085bb9b267

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 9, 5'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1G | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs970742328, COSV61719744; called by muse, mutect2, varscan2
- CSMD1 | c.3130G>A p.E1044K (on ENST00000520002; = p.E1043K on NM_033225.6) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV59346983; called by muse, mutect2, varscan2
- FAT4 | c.5419C>T p.R1807C | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746989506, COSV58685052; called by muse, mutect2, varscan2
- GH2 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs773390813, COSV60427069; called by muse, mutect2, varscan2
- NFAT5 | c.1257C>G p.I419M | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV63027164; called by muse, mutect2
- PABPC1L | c.1436C>T p.T479M | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs201624445; called by mutect2, varscan2
- SH3BP4 | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs576498199, COSV99060209; called by muse, mutect2, varscan2
- TECPR2 | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as COSV100849864, COSV63973676; called by muse, mutect2, varscan2
- ACVRL1 | c.868C>A p.Q290K | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); called by muse, mutect2
- AMER3 | c.512C>A p.T171N | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.329); called by muse, mutect2
- CCDC6 | c.1132G>T p.G378C | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- COPS2 | c.948-1G>C p.X316_splice | Splice Site (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- CYP2E1 | c.1269C>A p.Y423* | Nonsense Mutation (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- DCUN1D3 | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2
- DPP8 | c.2134C>T p.L712F (on ENST00000341861 / NM_001320875.2; = p.L696F on NM_130434.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- EXOC6B | c.1968C>A p.F656L | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); called by muse, varscan2
- FJX1 | c.842C>A p.A281E | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.094); called by muse, mutect2
- FREM1 | c.2042C>G p.T681R | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IRS2 | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- OR14C36 | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- PTEN | c.360_361insCC p.A121Pfs*14 | Frame Shift Ins (INS) | VAF 99/273 reads (36%) | called by mutect2, pindel, varscan2
- RC3H2 | c.782C>G p.S261C | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- RP1L1 | c.5533C>A p.Q1845K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- RPRD2 | c.3304C>A p.P1102T | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC10A3 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TACR3 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.22); called by muse, mutect2
- ZNF506 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CEMIP2 | c.3048G>A p.P1016= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs141686995; called by muse, mutect2, varscan2
- GPAT3 | c.243A>G p.K81= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV52356443; called by muse, mutect2
- GSTM4 | c.153C>T p.F51= | Silent (SNP) | VAF 17/174 reads (10%) | called by muse, mutect2, varscan2
- HMGCR | c.87C>T p.I29= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as rs1365225685; called by muse, mutect2, varscan2
- KDM6B | c.445C>A p.R149= | Silent (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- LRRC19 | c.448C>T p.L150= | Silent (SNP) | VAF 30/125 reads (24%) | called by muse, mutect2, varscan2
- POU3F4 | c.720G>A p.L240= | Silent (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- SKIL | c.526C>A p.R176= | Silent (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2
- SPTLC1 | c.120C>T p.F40= | Silent (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- SNX13 | c.-136G>A | 5'UTR (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
